TCGA case TCGA-V4-A9EE — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: Institut Curie. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/edbf6720-467e-4928-b1cb-0e7336358d18

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: France; Age at index: 86 years; Year of birth: 1926; Vital status: Dead; Days to death: 398 days (1.1 years); Year of death: 2013; Cause of death: Cancer Related.

Diagnoses (2)
1. Epithelioid cell melanoma (the primary disease): ICD-O-3 morphology code: 8771/3; ICD-10 code: C69.30; Tissue or organ of origin: Choroid; Site of resection or biopsy: Choroid; Classification of tumor: primary; Age at diagnosis: 86.0 years (31,421 days); Year of diagnosis: 2012; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T3a; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIB; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 398 days (1.1 years); Sites of involvement: Eye, Choroid.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 16.
   Pathology details: Consistent pathology review: Yes; Epithelioid cell percent range: >90%; Extrascleral extension present: No; Measurement type: Echographic; Tumor depth measurement: 11; Tumor shape: Dome.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -5 days; Residual disease: R0; Treatment anatomic sites: Eye.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Epithelioid cell melanoma), site: Liver. Age at diagnosis: 86.6 years (31,632 days); Days to diagnosis: 211 days; Prior treatment: Yes.

Follow-up (2 entries)
- Day 211 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 211 days.
- Days to follow up: 398 days (1.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 4.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 97 kg; Height: 178 cm; BMI: 30.6.
- Comorbidities: Diabetes, Type II.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-V4-A9EE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 40 mg.
  Slide TCGA-V4-A9EE-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-V4-A9EE-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-V4-A9EE-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Cause of death: Metastatic Uveal Melanoma.
- Primary pathology, Tumor morphology list, Tumor morphology: Histologic diagnosis: Epithelioid Cell; Tumor morphology percentage: >90%.
- Primary pathology: Tumor basal diameter mx: Pathologic Measurement; Tumor thickness measurement: Echographic Measurement.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 398 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 398 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 211 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-V4-A9EE-01A-11D-A39V-01): tumor purity 0.92, ploidy 1.98, whole-genome doublings 0.

Additional fields from the TCGA clinical supplement workbook ExtendedFollowUp_clinicalSupplement.xlsx:
- comorbidity: diabetes type 2
- days to metastasis: 211
- days to outcome: 29
- days to procedure 1: -5
- diagnosis: melanoma
- disease status at death: Evidence of Disease
- evaluated by imaging: no
- line of therapy 1: first
- m stage: M0
- morphologic subtype: epithelioid
- n stage: N0
- outcome: Progressive Disease
- resection status 1: R0
- staging system: AJCC
- t stage: T3a
- unresectable 1: no
